EXCEPTIONAL_RESPONDERS case ER-AD7D — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/69981b29-04b9-4b3f-b7f6-a4fc87c2cadf

Demographics
Sex at birth: female; Race: white; Year of birth: 1950; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Colon, NOS; Classification of tumor: metastasis; Age at diagnosis: 52.6 years (19,226 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Days to last follow up: 4,456 days (12.2 years); Days to best overall response: 2,161 days (5.9 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 2,026 days (5.5 years); Days to treatment end: 2,678 days (7.3 years).
   Treatment given: Therapeutic agents: Fluorouracil; Days to treatment start: 2,026 days (5.5 years); Days to treatment end: 2,120 days (5.8 years).
   Treatment given: Therapeutic agents: Irinotecan + Leucovorin Calcium; Days to treatment start: 2,026 days (5.5 years); Days to treatment end: 2,118 days (5.8 years).
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Cervix uteri; Age at diagnosis: 32.4 years (11,821 days); AJCC pathologic stage: Stage 0.

Follow-up (1 entry)
- Days to follow up: 4,456 days (12.2 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 4,456 days (12.2 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AD7D-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AD7D-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-AD7D-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AD7D-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 50; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
